Gene-level copy-number profile of tumor specimen TCGA-44-3918-01A from TCGA case TCGA-44-3918, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 60.9 years (22,236 days).
Specimen TCGA-44-3918-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.7122578c-b786-40b4-af7f-084916452d37.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-44-3918-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2 (2 files); ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ac8bc41f-15a3-4122-ba1d-08dba6bf08ef

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2,443; copy number 2: 15,644; copy number 3: 12,025; copy number 4: 17,192; copy number 5: 6,224; copy number 6: 2,510; copy number 7: 1,426; copy number 8: 2,087; copy number 9: 31; copy number 10: 123; copy number 11: 55; copy number 12: 6; copy number 13: 18; copy number 18: 25.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-44-3918-01A-01D-A273-01): tumor purity 0.45, ploidy 1.8, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 258 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:16,087,525–23,208,045, 99 genes, copy number 9–18 (within-gene range 4–18) (broad region; genes not listed).
- chr12:29,337,352–29,784,759, 6 genes, copy number 12 (within-gene range 6–12): ERGIC2, OVCH1-AS1, OVCH1, TMTC1, AC009320.1, RPL21P99.
- chr12:30,696,121–32,383,633, 60 genes, copy number 10–13 (within-gene range 5–13): AC012673.1, CAPRIN2, AC010198.1, LINC00941, AC010198.2, PPIAP44, TSPAN11, AC008013.1, AC008013.2, DDX11-AS1, DDX11, SNORA75, AC008013.3, AC024940.1, AC024940.4, AC024940.2, MREGP1, AC024940.5, SINHCAF, AC024940.3, FLJ13224, LINC02387, U6, DENND5B, RNU6-618P, AC068792.1, AC022080.1, AC022080.2, Y_RNA, ANKRD49P2, DENND5B-AS1, RNU5F-4P, RPL31P50, AK4P3, AC068774.1, ETFBKMT, AMN1, STMN1P1, AC023157.2, AC023157.1, IFITM3P2, H3-5, RNU6-1069P, AC023050.2, AC023050.3, LINC02422, AC023050.4, AC023050.1, RPL12P32, AC023050.5, RESF1, AC016957.2, AC016957.1, AC048344.2, AC048344.3, AC048344.1, BICD1, AC048344.4, AC016954.1, AC026356.1.
- chr14:22,147,995–22,533,560, 81 genes, copy number 10 (broad region; genes not listed).
- chr22:27,221,349–27,721,677, 12 genes, copy number 9: LINC01638, AL020994.3, AL020994.1, LINC02554, AL020994.2, AL049536.1, AL050402.2, AL050402.1, AL133456.1, AL121885.2, AL121885.3, AL121885.1.

Autosomal genes at a single copy (total copy number 1): 1,745. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
